Somatic mutation profile of cancer-model specimen HCM-SANG-0300-C15-85A (3D Organoid; aliquot HCM-SANG-0300-C15-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0300-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0300-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0cd9863c-58af-44dd-90e9-5f188101743a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0300-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0300-C15-10A-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1a80520c-6875-40e5-b690-aa2fd36050a7

The open-access MAF lists 138 somatic variants for this specimen: 107 protein-altering or splice-affecting, 27 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 82, Silent 27, Nonsense Mutation 11, Frame Shift Ins 6, Frame Shift Del 4, Intron 3, In Frame Ins 1, 3'UTR 1, In Frame Del 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 198/198 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.319); catalogued as rs28934578, CM062017, CM951224, COSV52661038, COSV52677601, COSV52731306, COSV53801286; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABCB11 | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 144/301 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as rs752992432, CM092737, COSV55590188, COSV99792711; called by muse, mutect2, varscan2
- AKAP3 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 132/308 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs576355339, COSV57413694; called by muse, varscan2
- ARID1A | c.5578G>T p.E1860* | Nonsense Mutation (SNP) | VAF 293/294 reads (100%) | catalogued as COSV61386185; called by muse, mutect2, varscan2
- BACH1 | c.1745T>C p.I582T | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54521331; called by muse, mutect2, varscan2
- BHLHE22 | c.754C>T p.R252C | Missense Mutation (SNP) | VAF 256/509 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100417975; called by muse, varscan2
- BSN | c.2531G>A p.R844Q | Missense Mutation (SNP) | VAF 260/260 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1427021565; called by muse, mutect2, varscan2
- BTG4 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 177/382 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs766954448, COSV100604619; called by muse, mutect2, varscan2
- CBX2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 274/542 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.263); catalogued as rs1555830980, COSV53970129; called by muse, mutect2, varscan2
- CCER1 | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 281/568 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as COSV100726964; called by muse, mutect2, varscan2
- CCR3 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 130/130 reads (100%) | catalogued as rs754911047, COSV62462585; called by muse, mutect2, varscan2
- CDC42EP2 | c.257C>T p.T86I | Missense Mutation (SNP) | VAF 339/701 reads (48%) | SIFT tolerated (0.4); PolyPhen benign (0.009); catalogued as rs751634350; called by muse, mutect2, varscan2
- CDKN2A | c.132C>A p.Y44* | Nonsense Mutation (SNP) | VAF 178/178 reads (100%) | catalogued as CM980323, COSV100446627, COSV58689440, COSV58696346, COSV58697475; called by muse, mutect2, varscan2
- CLEC1B | c.43C>T p.R15W | Missense Mutation (SNP) | VAF 97/246 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs186022027, COSV53726394; called by muse, mutect2, varscan2
- COL5A2 | c.4411C>T p.R1471C | Missense Mutation (SNP) | VAF 145/358 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1430667498, COSV66409145; called by muse, mutect2, varscan2
- DNAH9 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 172/172 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs750536301; called by muse, mutect2, varscan2
- EIF4E1B | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 235/436 reads (54%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.532); catalogued as rs1296660855, COSV53781927; called by muse, mutect2, varscan2
- HS6ST1 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 103/864 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.259); catalogued as rs1180961304; called by muse, mutect2
- IGFBPL1 | c.149C>T p.A50V | Missense Mutation (SNP) | VAF 228/230 reads (99%) | SIFT tolerated (0.7); PolyPhen benign (0.003); catalogued as rs1205112297; called by muse, varscan2
- KCNT2 | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 103/165 reads (62%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.594); catalogued as COSV54079855; called by muse, mutect2, varscan2
- KIF1A | c.2528G>A p.R843H | Missense Mutation (SNP) | VAF 213/443 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763193287; called by muse, mutect2, varscan2
- KLK8 | c.749A>C p.D250A | Missense Mutation (SNP) | VAF 388/578 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.209); catalogued as rs777146021; called by muse, mutect2, varscan2
- LRIG2 | c.950A>T p.D317V | Missense Mutation (SNP) | VAF 82/134 reads (61%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.566); catalogued as COSV63160821; called by muse, mutect2, varscan2
- MAP7 | c.430C>T p.R144W | Missense Mutation (SNP) | VAF 154/314 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs369036954; called by muse, mutect2, varscan2
- MB21D2 | c.931C>G p.Q311E | Missense Mutation (SNP) | VAF 173/348 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.403); catalogued as rs988241015, COSV66661548, COSV66661553; called by muse, mutect2, varscan2
- MELTF | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 230/473 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs1385392506; called by muse, mutect2, varscan2
- NCF4 | c.767C>T p.A256V | Missense Mutation (SNP) | VAF 309/314 reads (98%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs761060692, COSV50623764; called by muse, mutect2, varscan2
- NF1 | c.5128G>A p.D1710N (on ENST00000358273 / NM_001042492.3; = p.D1689N on NM_000267.3) | Missense Mutation (SNP) | VAF 229/476 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as rs1428709938; called by muse, mutect2, varscan2
- NKAPD1 | c.46C>T p.R16W | Missense Mutation (SNP) | VAF 188/411 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs1482125449, COSV99735573; called by muse, mutect2, varscan2
- NPAP1 | c.463G>T p.E155* | Nonsense Mutation (SNP) | VAF 210/214 reads (98%) | catalogued as COSV100276207, COSV61506825; called by muse, mutect2, varscan2
- PCLO | c.10119G>A p.W3373* | Nonsense Mutation (SNP) | VAF 153/380 reads (40%) | catalogued as COSV100435135; called by muse, mutect2, varscan2
- PEX14 | c.931A>T p.M311L | Missense Mutation (SNP) | VAF 296/573 reads (52%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.014); catalogued as rs761789278; called by muse, mutect2, varscan2
- PGR | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 163/338 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450222910, COSV54799232; called by muse, mutect2, varscan2
- PHYHIPL | c.586G>T p.D196Y | Missense Mutation (SNP) | VAF 83/202 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV65848440; called by muse, mutect2, varscan2
- PLIN4 | c.1321G>A p.V441M (on ENST00000301286; = p.V456M on NM_001367868.2) | Missense Mutation (SNP) | VAF 296/594 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs771476439, COSV56699405; called by muse, mutect2, varscan2
- PPM1K | c.937G>A p.V313I | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs776854512; called by muse, mutect2, varscan2
- PROCA1 | c.356del p.G119Afs*40 (on ENST00000439862 / NM_001366301.1; = p.G91Afs*40 on NM_152465.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 157/421 reads (37%) | catalogued as COSV99972595; called by mutect2, pindel, varscan2
- PXDNL | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 285/578 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs1218405990, COSV62482671; called by muse, mutect2, varscan2
- RGSL1 | c.2330C>T p.S777L | Missense Mutation (SNP) | VAF 58/187 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.468); catalogued as rs1251452541; called by muse, mutect2, varscan2
- SLC1A2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 272/421 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs371351716; called by muse, mutect2, varscan2
- SLITRK2 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 275/276 reads (100%) | SIFT tolerated (0.93); PolyPhen benign (0.013); catalogued as rs782305088, COSV100157813, COSV59422866; called by muse, mutect2, varscan2
- SPEG | c.2975C>T p.A992V | Missense Mutation (SNP) | VAF 283/567 reads (50%) | SIFT tolerated (0.24); PolyPhen benign (0.265); catalogued as rs766108579, COSV56666245; called by muse, varscan2
- SRGAP2B | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 219/502 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs781893653, COSV101523407; called by muse, mutect2, varscan2
- SRRM5 | c.1351C>T p.R451* | Nonsense Mutation (SNP) | VAF 294/686 reads (43%) | catalogued as rs1184172556; called by muse, mutect2, varscan2
- ST6GAL2 | c.746C>A p.A249E | Missense Mutation (SNP) | VAF 333/665 reads (50%) | PolyPhen benign (0.003); catalogued as COSV100868272; called by muse, mutect2, varscan2
- TGIF2LX | c.487C>A p.P163T | Missense Mutation (SNP) | VAF 286/287 reads (100%) | SIFT tolerated (0.17); PolyPhen benign (0.195); catalogued as COSV52214611; called by muse, mutect2, varscan2
- TPPP2 | c.356G>A p.R119H | Missense Mutation (SNP) | VAF 142/142 reads (100%) | SIFT deleterious (0.05); PolyPhen benign (0.048); catalogued as rs776993921; called by muse, mutect2, varscan2
- TTC28 | c.7135C>T p.R2379W | Missense Mutation (SNP) | VAF 252/252 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs573932994; called by muse, mutect2, varscan2
- TTN | c.76312C>A p.P25438T (on ENST00000591111; = p.P18014T on NM_003319.4) | Missense Mutation (SNP) | VAF 207/435 reads (48%) | PolyPhen probably damaging (0.999); catalogued as COSV60133654; called by muse, mutect2, varscan2
- TTN | c.10603C>T p.Q3535* (on ENST00000591111; = p.Q3489* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 187/362 reads (52%) | catalogued as COSV60162513; called by muse, mutect2, varscan2
- ZFP42 | c.791C>T p.T264M | Missense Mutation (SNP) | VAF 157/157 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1052462774, COSV58817514; called by muse, mutect2, varscan2
- ZNF146 | c.299T>G p.F100C | Missense Mutation (SNP) | VAF 150/422 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100757736; called by muse, mutect2, varscan2
- ZNF486 | c.398A>C p.K133T | Missense Mutation (SNP) | VAF 79/163 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs1555718115, COSV58720567; called by muse, mutect2, varscan2
- ZNF565 | c.728C>T p.A243V (on ENST00000355114; = p.A203V on NM_152477.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 430/698 reads (62%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs1023118580; called by muse, mutect2
- AMER1 | c.1843A>C p.T615P | Missense Mutation (SNP) | VAF 335/336 reads (100%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- AP4B1 | c.1036C>A p.Q346K | Missense Mutation (SNP) | VAF 90/335 reads (27%) | SIFT tolerated (0.77); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ATP9A | c.68+1G>A p.X23_splice | Splice Site (SNP) | VAF 178/406 reads (44%) | called by muse, mutect2
- BCL7A | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 35/412 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.24); called by muse, mutect2
- C10orf67 | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 97/97 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.545); called by muse, mutect2, varscan2
- CCDC57 | c.1359C>G p.S453R | Missense Mutation (SNP) | VAF 76/456 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CCDC6 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 197/313 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- CIC | c.4117_4118insG p.S1373Cfs*68 | Frame Shift Ins (INS) | VAF 266/647 reads (41%) | called by mutect2, pindel, varscan2
- CYP4A11 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 194/407 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CYYR1 | c.464A>T p.*155Lext*17 | Nonstop Mutation (SNP) | VAF 92/167 reads (55%) | called by muse, mutect2, varscan2
- ENC1 | c.1400A>G p.Q467R | Missense Mutation (SNP) | VAF 151/316 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESYT2 | c.1021C>T p.P341S (on ENST00000613624; = p.P265S on NM_020728.3) | Missense Mutation (SNP) | VAF 183/385 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- FAM98C | c.83G>T p.G28V | Missense Mutation (SNP) | VAF 294/587 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- FNIP1 | c.1342A>C p.K448Q | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.251); called by muse, mutect2, varscan2
- GALNT9 | c.101C>A p.S34Y | Missense Mutation (SNP) | VAF 303/612 reads (50%) | SIFT tolerated (0.95); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- GAS2L1 | c.815_819dup p.C274Tfs*49 | Frame Shift Ins (INS) | VAF 134/156 reads (86%) | called by mutect2, varscan2
- GNPAT | c.1742A>T p.Q581L | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- GPR27 | c.611T>C p.L204P | Missense Mutation (SNP) | VAF 144/1723 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- HLA-A | c.694_695dup p.Y233Sfs*8 | Frame Shift Ins (INS) | VAF 86/352 reads (24%) | called by mutect2, varscan2
- KMT2C | c.12354del p.P4119Qfs*39 | Frame Shift Del (DEL) | VAF 174/416 reads (42%) | called by mutect2, pindel, varscan2
- KPNA1 | c.151_154dup p.T52Sfs*19 | Frame Shift Ins (INS) | VAF 82/200 reads (41%) | called by mutect2, pindel, varscan2
- LDLRAD3 | c.959G>T p.S320I | Missense Mutation (SNP) | VAF 332/979 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- MAGEL2 | c.266T>A p.I89K | Missense Mutation (SNP) | VAF 270/273 reads (99%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAP3K9 | c.1588G>T p.V530L | Missense Mutation (SNP) | VAF 92/229 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- MAP7 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 163/366 reads (45%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MCM8 | c.1525C>G p.L509V | Missense Mutation (SNP) | VAF 12/306 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MUCL3 | c.79G>A p.A27T | Missense Mutation (SNP) | VAF 204/466 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- NCALD | c.89G>A p.W30* | Nonsense Mutation (SNP) | VAF 198/419 reads (47%) | called by muse, mutect2, varscan2
- NR2F6 | c.701_706del p.L234_L235del | In Frame Del (DEL) | VAF 126/765 reads (16%) | called by mutect2, pindel, varscan2
- OR56A4 | c.710dup p.S238Vfs*8 | Frame Shift Ins (INS) | VAF 160/166 reads (96%) | called by mutect2, varscan2
- OR56A4 | c.709delinsAT p.L237Ifs*9 | Frame Shift Ins (INS) | VAF 166/332 reads (50%) | called by mutect2*, pindel, varscan2*
- OR5D13 | c.808A>T p.S270C | Missense Mutation (SNP) | VAF 178/363 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PDZRN4 | c.1557G>T p.M519I (on ENST00000402685 / NM_001164595.2; = p.M261I on NM_013377.4) | Missense Mutation (SNP) | VAF 111/224 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PNPT1 | c.833C>T p.T278I | Missense Mutation (SNP) | VAF 118/301 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- PPP1R3A | c.681T>A p.Y227* | Nonsense Mutation (SNP) | VAF 140/258 reads (54%) | called by muse, mutect2, varscan2
- PTX4 | c.8G>A p.C3Y | Missense Mutation (SNP) | VAF 131/216 reads (61%) | SIFT deleterious (0.01); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- REN | c.202A>G p.T68A | Missense Mutation (SNP) | VAF 205/294 reads (70%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- RWDD2B | c.957A>T p.Q319H | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SPHK2 | c.652_653del p.I218Pfs*19 | Frame Shift Del (DEL) | VAF 165/377 reads (44%) | called by mutect2, pindel, varscan2
- SPTBN5 | c.10288G>T p.E3430* | Nonsense Mutation (SNP) | VAF 298/300 reads (99%) | called by muse, mutect2, varscan2
- SYNM | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 299/698 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TBX5 | c.181A>T p.R61* | Nonsense Mutation (SNP) | VAF 205/413 reads (50%) | called by muse, mutect2, varscan2
- TEKT2 | c.1117C>A p.L373M | Missense Mutation (SNP) | VAF 237/475 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- TMEM53 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 276/604 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TRAF6 | c.328del p.E110Kfs*21 | Frame Shift Del (DEL) | VAF 157/540 reads (29%) | called by mutect2, pindel, varscan2
- TSPAN12 | c.778A>G p.M260V | Missense Mutation (SNP) | VAF 139/305 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSTD2 | c.102C>G p.S34R | Missense Mutation (SNP) | VAF 119/290 reads (41%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- TUSC3 | c.457C>G p.H153D | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- TYR | c.858G>C p.Q286H | Missense Mutation (SNP) | VAF 147/291 reads (51%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- UBA2 | c.451A>G p.I151V | Missense Mutation (SNP) | VAF 198/295 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- WWC1 | c.1845_1865dup p.A616_V622dup | In Frame Ins (INS) | VAF 85/212 reads (40%) | called by mutect2, varscan2
- ZBTB17 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 254/551 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF723 | c.241T>C p.F81L | Missense Mutation (SNP) | VAF 38/96 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ACTL8 | c.459C>T p.G153= | Silent (SNP) | VAF 261/541 reads (48%) | called by muse, mutect2, varscan2
- AGAP4 | c.1077C>T p.S359= | Silent (SNP) | VAF 272/350 reads (78%) | called by muse, varscan2
- ARHGAP27 | c.546C>T p.S182= | Silent (SNP) | VAF 370/758 reads (49%) | called by muse, mutect2, varscan2
- BOD1L1 | c.4260C>T p.P1420= | Silent (SNP) | VAF 205/206 reads (100%) | called by muse, mutect2, varscan2
- C3orf22 | c.111C>A p.P37= | Silent (SNP) | VAF 192/415 reads (46%) | catalogued as COSV100559543; called by muse, mutect2, varscan2
- CDHR2 | c.2379C>T p.D793= | Silent (SNP) | VAF 238/522 reads (46%) | catalogued as rs776599507, COSV56134974; called by muse, mutect2, varscan2
- CHRM2 | c.756C>T p.D252= | Silent (SNP) | VAF 160/367 reads (44%) | catalogued as rs531986911, COSV57765140, COSV57779856; called by muse, mutect2, varscan2
- CLEC11A | c.567G>T p.L189= | Silent (SNP) | VAF 357/1069 reads (33%) | called by muse, varscan2
- DNM1 | c.564G>A p.K188= | Silent (SNP) | VAF 18/444 reads (4%) | called by muse, mutect2
- DOCK10 | c.4416C>T p.I1472= | Silent (SNP) | VAF 86/176 reads (49%) | catalogued as rs1323910530, COSV51425814; called by muse, mutect2, varscan2
- DUXA | c.6C>T p.A2= | Silent (SNP) | VAF 140/469 reads (30%) | catalogued as rs564812746, COSV73729497; called by muse, mutect2, varscan2
- FLG | c.5202G>C p.V1734= | Silent (SNP) | VAF 213/459 reads (46%) | catalogued as rs1189669276; called by muse, mutect2, varscan2
- FZD1 | c.1668C>T p.F556= | Silent (SNP) | VAF 72/355 reads (20%) | catalogued as rs779835319; called by muse, mutect2, varscan2
- IGSF11 | c.408C>T p.T136= (on ENST00000393775 / NM_001015887.3; = p.T135= on NM_152538.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 118/257 reads (46%) | catalogued as rs775388268; called by muse, mutect2, varscan2
- KCNH6 | c.1929C>T p.R643= | Silent (SNP) | VAF 250/495 reads (51%) | called by muse, mutect2, varscan2
- KIF26B | c.5667C>T p.F1889= | Silent (SNP) | VAF 86/583 reads (15%) | catalogued as COSV63649935; called by muse, mutect2, varscan2
- LAMB1 | c.2433T>C p.F811= | Silent (SNP) | VAF 266/543 reads (49%) | called by muse, mutect2, varscan2
- MS4A6A | c.126C>T p.H42= | Silent (SNP) | VAF 165/332 reads (50%) | catalogued as rs113133013, COSV60617004; called by muse, mutect2, varscan2
- MYO7A | c.1530C>T p.I510= | Silent (SNP) | VAF 136/280 reads (49%) | catalogued as rs746423219; called by muse, mutect2, varscan2
- PAPLN | c.1623C>A p.P541= (on ENST00000554301; = p.P514= on NM_173462.4) | Silent (SNP) | VAF 72/164 reads (44%) | called by muse, mutect2, varscan2
- POU4F2 | c.240C>T p.G80= | Silent (SNP) | VAF 272/273 reads (100%) | catalogued as COSV99850193; called by muse, mutect2, varscan2
- SBK1 | c.450G>A p.T150= | Silent (SNP) | VAF 269/538 reads (50%) | catalogued as rs933990892, COSV59399102; called by muse, mutect2, varscan2
- SDK2 | c.1242C>T p.I414= | Silent (SNP) | VAF 219/429 reads (51%) | catalogued as rs761629975, COSV101167947; called by muse, mutect2, varscan2
- SPANXN1 | c.159G>A p.A53= | Silent (SNP) | VAF 178/178 reads (100%) | catalogued as rs782807503, COSV65122958, COSV65123182; called by muse, mutect2, varscan2
- TRPM2 | c.1488G>A p.K496= | Silent (SNP) | VAF 144/372 reads (39%) | called by muse, mutect2, varscan2
- WDR49 | c.576C>T p.N192= (on ENST00000308378 / NM_001366158.1; = p.N533= on NM_001348951.2 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 207/386 reads (54%) | catalogued as rs372277287; called by muse, mutect2, varscan2
- ZNF70 | c.1191C>A p.G397= | Silent (SNP) | VAF 272/274 reads (99%) | called by muse, mutect2
- ATP11A | c.*1035C>T | 3'UTR (SNP) | VAF 396/396 reads (100%) | catalogued as rs1440326955; called by muse, mutect2, varscan2
- OSGIN2 | c.-89+691_-89+705del | Intron (DEL) | VAF 124/372 reads (33%) | called by mutect2, pindel, varscan2
- TASOR | c.2765-80G>A | Intron (SNP) | VAF 64/149 reads (43%) | called by muse, mutect2, varscan2
- ZNF160 | c.271+662G>T | Intron (SNP) | VAF 302/439 reads (69%) | called by muse, mutect2, varscan2
